Surgical pathology report (de-identified scan), TCGA case TCGA-FV-A3I1, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-FV-A3I1-01A (Primary Tumor).

[page 1 of 3]
Requested by:

Patient
MRN
DOB
Date of Service
Performing Facility
Ordering Provider
Result Provider
Report Name : Surgical Report
Status : F

P review date	Jan 12/2/11	12/1/11

Surgical Report - STATUS: Final

see text

Ordered By:

Facility:

Perform Date:

Ordered Date:

Department:

Service Report. Text

LABORATORY

Procedure Date and Time:

SURGICAL PATHOLOGY REPORT

MED REC #:

DIAGNOSIS:

LIVER, RIGHT LOBE (PARTIAL RESECTION): HEPATOCELLULAR CARCINOMA, WELL

TO MODERATELY TO POORLY DIFFERENTIATED

GALLBLADDER: MILD CHRONIC CHOLECYSTITIS

SYNOPTIC REPORT:

1. SPECIMEN: LIVER AND GALLBLADDER

2. PROCEDURE: PARTIAL HEPATECTOMY

- MINOR HEPATECTOMY (LESS THAN 3 SEGMENTS)

3. TUMOR SIZE:

- GREATEST DIMENSION: 4.0 CM

- ADDITIONAL DIMENSIONS: 4.0 X 3.0 CM

4. TUMOR FOCALITY: SOLITARY: RIGHT LOBE

5. HISTOLOGIC TYPE: HEPATOCELLULAR CARCINOMA

6. HISTOLOGIC GRADE: STEINER and EDMONDSON GII to GIV

7. TUMOR EXTENSION: TUMOR CONFINED TO LIVER

8. MARGINS:

- PARENCHYMAL MARGIN: UNINVOLVED BY INVASIVE CARCINOMA

- CLOSEST MARGIN: 1 MM

9. LYMPH-VASCULAR INVASION:

- MACROSCOPIC: NOT IDENTIFIED

- MICROSCOPIC: PRESENT

10. PERINEURAL INVASION: NOT IDENTIFIED

11. PATHOLOGIC STAGING:

- pT2: SOLITARY TUMOR WITH VASCULAR INVASION

- REGIONAL LYMPH NODES: pN0:

- NUMBER OF LYMPH NODES EXAMINED: 1

- DISTANT METASTASES: NOT APPLICABLE

12. ADDITIONAL PATHOLOGIC FINDINGS:

- FIBROSIS SCORE: NONE (ISHAK STAGE 0): F0

CPT: 88304, 88307, 88342 X18

COMMENT:

The case was reviewed in the Pathology Department

1CD-0-3

carcinoma, hepatocellular, NOS 8170/3

Site: liver C22.0

hw
12/2/11

[page 2 of 3]
Patient

MRN

DOB

Date of Service :

Performing Facility

Ordering Provider :

Result Provider :

Report Name :Surgical Report

Status :F DXSTIC X

Requested by:

and discussed with Dr

MICROSCOPIC DESCRIPTION:-----

The non-neoplastic liver, seen best in blocks 1, 3 and 10, shows no evidence of cirrhosis. Tumor is present in blocks 1-5 and 7-12. Sections of the tumor demonstrate hepatocellular carcinoma with variable features. There are areas with solid and trabecular growth, typical of hepatocellular carcinoma, and some areas with desmoplastic stroma and a suggestion of glandular growth. Some areas are well differentiated (grade 2) while others are moderately (grade 3) and poorly differentiated (grade 4) with anaplastic giant cells and numerous mitotic figures. Some areas have tumor cells with cytoplasmic fat, and some areas have hyaline globules. The surgical margins are negative, but the satellite nodule noted grossly (block 3) is within 1 mm of the inked margin. The immunostain results support the diagnosis of hepatocellular carcinoma.

SPECIAL STAINS:-----

Immunostains (blocks 1 and 5):

Alpha fetoprotein Strongly positive

Glypican-3 Strongly positive

Polyclonal CEA Canalicular staining predominantly

HepPar-1 Variable patchy positivity

Cytokeratin 8 Positive in majority of tumor

Cytokeratin 7 Variable positivity, 10 to 25% of tumor cells

Cytokeratin 19 A few areas of positivity, most of tumor negative

EMA Scattered positivity, <2% of tumor cells

MOC-31 Patchy positivity, 25 to 50% of tumor

PRE-OPERATIVE DIAGNOSIS:-----

Liver lesion

POST-OPERATIVE DIAGNOSIS:-----

Same, pending pathology

CLINICAL INFORMATION:-----

None provided

SPECIMEN:

GALLBLADDER, PORTION OF LIVER -----

GROSS DESCRIPTION:-----

The specimen is received in one part and is labeled with the patient's name [REDACTED] and "portion of liver and gallbladder." The specimen consists of a portion of liver with attached gallbladder. The portion of liver measures 8.0 x 5.5 x 3.5 cm. The capsular surface is tan-white and bosselated. The resection surface is inked black, and the specimen is serially sectioned. The specimen consists of a well-defined, irregular tan-white nodule, measuring about 4.0 x 4.0 x 3.0 cm. The nodule is composed of tan-white firm tissue and is 0.3 cm

[page 3 of 3]
Patient [REDACTED]
MRN [REDACTED]
DOB [REDACTED]
Date of Service :
Performing Facility :
Ordering Provider :
Result Provider :
Report Name :Surgical Report
Status :F X

Requested by:

to the closest resection margin. The small separate nodule is 0.3 cm away from the larger nodule. The remaining specimen shows tan-brown unremarkable hepatic parenchyma. The attached gallbladder measures 7.5 cm in length x 3.0 cm in diameter. The cystic duct measures 0.1 cm in length x 0.3 cm in diameter. The serosal surface is smooth and congested. One lymph node, measuring 1.0 cm in length is identified adjacent to the cystic duct. The mucosal surface is bile stained without ulceration. The lumen contains dark green bile without calculi. The gallbladder wall measures 0.1 cm in thickness. Representative sections are submitted in six cassettes as follows: cassette 1 - larger nodule with resection margin; cassette 2 - nodule with external adherent gallbladder wall; cassette 3 - small separate nodule with surgical margin; cassettes 4 and 5 - random sections of larger nodule; cassette 6 - gallbladder and lymph node.

ADDENDUM

Additional sections are submitted in six cassettes, labeled cassettes 7 through 12. (
<Sign Out Dr. Signature>

End of Report

MED REC #: [REDACTED]

Source: NCI Genomic Data Commons file 99f7d9a8-1b4a-457c-a8f6-284d748939ab (TCGA-FV-A3I1.B40A8E73-2904-4C68-B2AD-6FC27211654B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).